Somatic mutation profile of tumor specimen TCGA-S4-A8RP-01A (aliquot TCGA-S4-A8RP-01A-11D-A36O-08) from TCGA case TCGA-S4-A8RP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.6 years (28,353 days).
Specimen TCGA-S4-A8RP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23d0ad1f-9bfe-44c7-b477-596cbc78bbdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S4-A8RP-10A (Blood Derived Normal), aliquot TCGA-S4-A8RP-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc663b79-1a8d-4c0d-8ddd-ebba9a9fdb1d

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 89/399 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1054G>T p.G352* | Nonsense Mutation (SNP) | VAF 131/372 reads (35%) | hotspot (GDC flag); catalogued as CM024126, COSV61684989, COSV61690191; called by muse, mutect2, varscan2
- CELF3 | c.345T>G p.F115L | Missense Mutation (SNP) | VAF 118/1433 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99310686; called by muse, mutect2
- CLSTN3 | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99867879; called by muse, mutect2, varscan2
- DCTN1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 122/534 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs763277715, COSV62620825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX55 | c.1193G>T p.R398I | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99434929; called by muse, mutect2, varscan2
- FTSJ3 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 122/562 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); catalogued as COSV100835139; called by muse, mutect2, varscan2
- GAS7 | c.263C>T p.S88L (on ENST00000432992 / NM_201433.2; = p.S28L on NM_201432.2) | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764521353, COSV60434218; called by muse, mutect2, varscan2
- GOLGA3 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.209); catalogued as COSV52647381, COSV99213308; called by muse, mutect2, varscan2
- HTR1A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs1467451068, COSV100109350; called by muse, mutect2
- NUB1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 130/496 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100879415; called by muse, mutect2, varscan2
- PCDHB7 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782283058, COSV50753965; called by muse, mutect2, varscan2
- PLPP2 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 47/232 reads (20%) | catalogued as COSV99514874; called by muse, mutect2, varscan2
- PRAMEF1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 152/459 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs534609491, COSV60005028, COSV60007201; called by muse, mutect2, varscan2
- RELN | c.9416T>C p.V3139A | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100635225; called by muse, mutect2, varscan2
- SLCO1B3 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 156/662 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410549391, COSV53941299, COSV53946057, COSV99682473; called by muse, mutect2, varscan2
- SRL | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 213/793 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101281378; called by muse, mutect2, varscan2
- WNT2B | c.775C>T p.R259C (on ENST00000369684 / NM_024494.3; = p.R240C on NM_004185.4) | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201153849, COSV56675972; called by muse, mutect2, varscan2
- ZNF516 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101487393; called by muse, mutect2, varscan2
- JAGN1 | c.422dup p.S143Ffs*41 | Frame Shift Ins (INS) | VAF 117/482 reads (24%) | called by mutect2, pindel, varscan2
- SGK1 | c.663-6_663-2del p.X221_splice | Splice Site (DEL) | VAF 83/307 reads (27%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6891C>T p.A2297= | Silent (SNP) | VAF 70/276 reads (25%) | catalogued as COSV99603761; called by muse, mutect2, varscan2
- CHIT1 | c.288C>T p.I96= | Silent (SNP) | VAF 66/311 reads (21%) | catalogued as rs539275442, COSV55148892; called by muse, mutect2, varscan2
- GTPBP4 | c.1461T>A p.I487= | Silent (SNP) | VAF 77/294 reads (26%) | catalogued as COSV100673001; called by muse, mutect2, varscan2
- LRRC4B | c.1875C>A p.P625= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as rs776283499, COSV100976097, COSV65350623; called by muse, mutect2, varscan2
- MACF1 | c.22003T>C p.L7335= (on ENST00000372915; = p.L5380= on NM_012090.5) | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as COSV99247703; called by muse, mutect2, varscan2
- MCTP2 | c.2082C>T p.F694= | Silent (SNP) | VAF 111/597 reads (19%) | catalogued as rs200511099, COSV59145214; called by muse, mutect2, varscan2
- NFKBIB | c.930C>T p.P310= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs1161853609, COSV100548574; called by muse, mutect2, varscan2
- ZNF451 | c.3024A>G p.G1008= (on ENST00000370706 / NM_001031623.3; = p.G960= on NM_015555.2) | Silent (SNP) | VAF 116/472 reads (25%) | catalogued as COSV100675194; called by muse, mutect2, varscan2
- FASTKD3 | c.-127C>T | 5'UTR (SNP) | VAF 16/78 reads (21%) | catalogued as rs1227659890, COSV52942766; called by muse, mutect2
- TRAK1 | c.1963+187C>A | Intron (SNP) | VAF 321/1360 reads (24%) | catalogued as COSV100410419; called by muse, mutect2, varscan2
